Somatic mutation profile of tumor specimen ALCH-B36Z-TTP1-A (aliquot ALCH-B36Z-TTP1-A-1-0-D-A780-36) from ALCHEMIST case ALCH-B36Z, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 62.5 years (22,810 days).
Specimen ALCH-B36Z-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7ab7733a-eaaf-4276-a8aa-e6e60e4286f4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B36Z-NB1-A (Blood Derived Normal), aliquot ALCH-B36Z-NB1-A-1-0-D-A780-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ad6136f7-e8ee-475d-95ee-fa6b4b72c7fe

The open-access MAF lists 391 somatic variants for this specimen: 274 protein-altering or splice-affecting, 70 silent, 47 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 231, Silent 70, Intron 21, Nonsense Mutation 16, Splice Site 9, 5'UTR 9, Frame Shift Del 8, RNA 6, 5'Flank 6, 3'UTR 3, Frame Shift Ins 3, Translation Start Site 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 126/380 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- ADAMTS20 | c.1118G>T p.G373V | Missense Mutation (SNP) | VAF 46/114 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67134824; called by muse, varscan2
- ADCY2 | c.1477C>A p.R493S | Missense Mutation (SNP) | VAF 38/237 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.465); catalogued as COSV57874000, COSV57900327; called by muse, mutect2, varscan2
- ADCY8 | c.1056G>T p.E352D | Missense Mutation (SNP) | VAF 119/402 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.239); catalogued as COSV53907314, COSV53907324; called by muse, mutect2, varscan2
- AGBL1 | c.2861T>C p.M954T | Missense Mutation (SNP) | VAF 26/149 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.438); catalogued as rs916298220; called by muse, mutect2, varscan2
- ARL6 | c.447A>T p.L149F | Missense Mutation (SNP) | VAF 24/97 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV60117463; called by muse, varscan2
- ASTN2 | c.785C>T p.P262L | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.205); catalogued as rs1284097201, COSV57751073, COSV57791053; called by mutect2, varscan2
- C9orf57 | c.128G>A p.R43H (on ENST00000377024 / NM_001371610.1; = p.R21H on NM_001128618.2) | Missense Mutation (SNP) | VAF 76/204 reads (37%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as rs376186692; called by muse, mutect2, varscan2
- CACNA1C | c.5053G>T p.E1685* | Nonsense Mutation (SNP) | VAF 73/178 reads (41%) | catalogued as rs768415458, COSV59739665; called by muse, mutect2, varscan2
- CAMK1G | c.182G>A p.R61Q | Missense Mutation (SNP) | VAF 175/290 reads (60%) | SIFT tolerated (0.09); PolyPhen benign (0.055); catalogued as rs759054187; called by muse, mutect2, varscan2
- CES3 | c.1425C>A p.D475E | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.03); catalogued as COSV100309887; called by muse, mutect2, varscan2
- CFTR | c.2393C>A p.P798H | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT deleterious (0.01); PolyPhen benign (0.33); catalogued as COSV99134728; called by muse, mutect2, varscan2
- CLVS2 | c.70C>T p.P24S | Missense Mutation (SNP) | VAF 59/156 reads (38%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.91); catalogued as COSV51568889; called by muse, mutect2, varscan2
- CNTNAP2 | c.899G>T p.R300L | Missense Mutation (SNP) | VAF 142/285 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.888); catalogued as COSV62163736, COSV62175685; called by muse, mutect2, varscan2
- CTNNA2 | c.897C>G p.F299L | Missense Mutation (SNP) | VAF 85/122 reads (70%) | SIFT tolerated (0.65); PolyPhen benign (0.105); catalogued as COSV63568298; called by muse, mutect2, varscan2
- CYYR1 | c.283C>G p.R95G | Missense Mutation (SNP) | VAF 103/217 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.767); catalogued as COSV54836151, COSV99051262; called by muse, mutect2, varscan2
- DEAF1 | c.69_98del p.A24_A33del | In Frame Del (DEL) | VAF 16/79 reads (20%) | catalogued as rs754135731; called by mutect2, varscan2*
- DMXL2 | c.2474A>G p.Q825R | Missense Mutation (SNP) | VAF 103/284 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs771843111; called by muse, mutect2, varscan2
- DOCK2 | c.4786C>T p.R1596* | Nonsense Mutation (SNP) | VAF 19/195 reads (10%) | catalogued as COSV56951180, COSV99914045; called by muse, mutect2, varscan2
- DSG3 | c.1970C>A p.P657Q | Missense Mutation (SNP) | VAF 141/533 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV57130077; called by muse, mutect2, varscan2
- F2RL1 | c.253G>T p.V85L | Missense Mutation (SNP) | VAF 82/199 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1374345905; called by muse, mutect2, varscan2
- FANCM | c.1949A>G p.E650G | Missense Mutation (SNP) | VAF 122/302 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.04); catalogued as rs771567101; called by muse, mutect2, varscan2
- FGD4 | c.2T>A p.M1? | Translation Start Site (SNP) | VAF 63/204 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.095); catalogued as COSV65941669; called by muse, mutect2, varscan2
- FLG | c.4610C>A p.P1537H | Missense Mutation (SNP) | VAF 90/620 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV100912167; called by muse, mutect2, varscan2
- GABBR2 | c.1270G>T p.G424W | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52311262, COSV99411191; called by muse, mutect2, varscan2
- GFRA2 | c.1225G>T p.G409W | Missense Mutation (SNP) | VAF 73/230 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV100151347; called by muse, mutect2, varscan2
- GPR12 | c.112C>A p.P38T | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT tolerated (0.21); PolyPhen benign (0.01); catalogued as rs1434917671, COSV67344043; called by muse, mutect2, varscan2
- GPR158 | c.1433C>T p.T478I | Missense Mutation (SNP) | VAF 36/303 reads (12%) | SIFT tolerated (0.69); PolyPhen benign (0.05); catalogued as COSV100894425; called by muse, mutect2, varscan2
- IL16 | c.335G>A p.R112Q | Missense Mutation (SNP) | VAF 38/198 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as rs200454423; called by muse, mutect2, varscan2
- KCNQ2 | c.1627G>T p.V543L (on ENST00000359125 / NM_172107.4; = p.V515L on NM_004518.6) | Missense Mutation (SNP) | VAF 320/520 reads (62%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.476); catalogued as COSV60554922; called by muse, mutect2, varscan2
- KCNV2 | c.454G>C p.D152H | Missense Mutation (SNP) | VAF 149/374 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs377667539, CM162525, COSV66056902; called by muse, mutect2, varscan2
- KEAP1 | c.1264G>A p.D422N | Missense Mutation (SNP) | VAF 9/14 reads (64%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.637); catalogued as COSV50280001, COSV50342418, COSV50645187; called by muse, mutect2, varscan2
- KIF26A | c.3412C>A p.L1138M | Missense Mutation (SNP) | VAF 29/80 reads (36%) | SIFT tolerated (0.27); PolyPhen benign (0.015); catalogued as COSV100181111; called by muse, mutect2, varscan2
- KIRREL3 | c.2261C>G p.S754C | Missense Mutation (SNP) | VAF 111/156 reads (71%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as rs1341563092; called by muse, mutect2, varscan2
- KRT26 | c.223G>A p.E75K | Missense Mutation (SNP) | VAF 201/552 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.698); catalogued as rs1425563093; called by muse, mutect2, varscan2
- KRT85 | c.1345C>A p.R449S | Missense Mutation (SNP) | VAF 74/248 reads (30%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.554); catalogued as rs1415689392; called by muse, mutect2, varscan2
- KRTAP21-3 | c.133G>C p.V45L | Missense Mutation (SNP) | VAF 42/99 reads (42%) | PolyPhen benign (0.205); catalogued as COSV71480763; called by muse, mutect2, varscan2
- MAPK15 | c.1244C>T p.S415F | Missense Mutation (SNP) | VAF 32/73 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.086); catalogued as COSV62028695; called by muse, mutect2, varscan2
- MGAM2 | c.4084G>A p.E1362K | Missense Mutation (SNP) | VAF 84/360 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.078); catalogued as rs1307627423; called by muse, varscan2
- MOCS1 | c.175G>A p.A59T | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT tolerated (0.53); PolyPhen benign (0.404); catalogued as rs770756364; called by muse, mutect2, varscan2
- MON1B | c.1063A>C p.T355P | Missense Mutation (SNP) | VAF 36/85 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.072); catalogued as COSV50254393; called by muse, mutect2, varscan2
- MUC3A | c.827C>A p.A276D | Missense Mutation (SNP) | VAF 287/565 reads (51%) | SIFT deleterious, low confidence (0.02); catalogued as rs759745439; called by muse, mutect2, varscan2
- NELL1 | c.87G>C p.Q29H | Missense Mutation (SNP) | VAF 113/213 reads (53%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV54344006; called by muse, mutect2, varscan2
- NIM1K | c.118G>A p.G40R | Missense Mutation (SNP) | VAF 65/224 reads (29%) | SIFT tolerated (0.44); PolyPhen benign (0.009); catalogued as COSV100390484; called by muse, mutect2, varscan2
- NLRP7 | c.2147C>A p.P716H (on ENST00000340844 / NM_206828.3; = p.P688H on NM_139176.3) | Missense Mutation (SNP) | VAF 103/306 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as CD094507, COSV100052815; called by muse, mutect2, varscan2
- NPR2 | c.2965C>T p.R989* | Nonsense Mutation (SNP) | VAF 220/730 reads (30%) | catalogued as COSV52415563; called by muse, mutect2, varscan2
- NRCAM | c.3352C>T p.R1118W | Missense Mutation (SNP) | VAF 127/269 reads (47%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.935); catalogued as rs79342974, COSV100695246; called by muse, mutect2, varscan2
- OR4P4 | c.151C>G p.Q51E | Missense Mutation (SNP) | VAF 55/137 reads (40%) | SIFT tolerated (0.26); PolyPhen benign (0.009); catalogued as COSV58921863; called by muse, mutect2, varscan2
- OR6C3 | c.699G>T p.K233N | Missense Mutation (SNP) | VAF 80/350 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as COSV65570912; called by muse, mutect2, varscan2
- OTC | c.953C>A p.S318Y | Missense Mutation (SNP) | VAF 129/199 reads (65%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.924); catalogued as CM003038, COSV99233914; called by muse, mutect2, varscan2
- PABPC1L | c.452C>T p.A151V | Missense Mutation (SNP) | VAF 72/102 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV53838668; called by muse, varscan2
- PCDH11Y | c.158C>A p.S53Y (on ENST00000400457 / NM_032973.2; = p.S42Y on NM_032971.3) | Missense Mutation (SNP) | VAF 287/362 reads (79%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as COSV53081627, COSV53084994; called by muse, mutect2, varscan2
- PCDHA1 | c.1303C>A p.L435M | Missense Mutation (SNP) | VAF 84/141 reads (60%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV65376889; called by muse, mutect2, varscan2
- PCDHB2 | c.2093C>T p.S698L | Missense Mutation (SNP) | VAF 130/233 reads (56%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.081); catalogued as COSV50564387; called by muse, mutect2, varscan2
- POTEC | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 108/250 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.53); catalogued as rs1291875658; called by muse, mutect2, varscan2
- PPP1R3A | c.3315G>T p.L1105F | Missense Mutation (SNP) | VAF 20/36 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1284071039; called by muse, mutect2
- RGS2 | c.347G>T p.C116F | Missense Mutation (SNP) | VAF 368/663 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52459195; called by muse, mutect2, varscan2
- SACS | c.10864C>A p.Q3622K | Missense Mutation (SNP) | VAF 85/256 reads (33%) | SIFT tolerated (0.45); PolyPhen probably damaging (0.952); catalogued as COSV66545846; called by muse, mutect2, varscan2
- SCFD2 | c.328G>T p.A110S | Missense Mutation (SNP) | VAF 28/103 reads (27%) | SIFT tolerated (0.81); PolyPhen benign (0.027); catalogued as COSV66376390; called by muse, mutect2, varscan2
- SCN8A | c.1516G>T p.G506* | Nonsense Mutation (SNP) | VAF 74/207 reads (36%) | catalogued as rs758393038; called by muse, mutect2, varscan2
- SEH1L | c.682G>T p.A228S | Missense Mutation (SNP) | VAF 50/212 reads (24%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.922); catalogued as COSV50816444; called by muse, varscan2
- SH2D7 | c.353C>T p.T118I | Missense Mutation (SNP) | VAF 28/107 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs762363688; called by muse, mutect2, varscan2
- SMARCAD1 | c.1573-1G>T p.X525_splice | Splice Site (SNP) | VAF 91/212 reads (43%) | catalogued as COSV100759055; called by muse, mutect2, varscan2
- SSC5D | c.688C>T p.R230C | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs748120226; called by muse, mutect2, varscan2
- STRN4 | c.475G>T p.V159L | Missense Mutation (SNP) | VAF 49/146 reads (34%) | SIFT tolerated (0.45); PolyPhen benign (0.055); catalogued as rs201535838, COSV99623702; called by muse, mutect2, varscan2
- STYXL2 | c.2395C>A p.L799M | Missense Mutation (SNP) | VAF 131/234 reads (56%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.963); catalogued as rs148873336; called by mutect2, varscan2
- TMEM131 | c.4915G>T p.G1639* | Nonsense Mutation (SNP) | VAF 70/228 reads (31%) | catalogued as COSV51786158; called by muse, mutect2, varscan2
- TP53 | c.596dup p.N200Kfs*9 | Frame Shift Ins (INS) | VAF 115/373 reads (31%) | catalogued as COSV52981553; called by mutect2, pindel, varscan2
- TRIM56 | c.350C>T p.T117M | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as rs1411521784; called by muse, mutect2, varscan2
- TRIO | c.7666A>G p.M2556V | Missense Mutation (SNP) | VAF 63/213 reads (30%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.347); catalogued as rs955511080; called by muse, mutect2, varscan2
- TRRAP | c.100+1G>T p.X34_splice | Splice Site (SNP) | VAF 42/88 reads (48%) | catalogued as COSV100722317; called by muse, mutect2, varscan2
- VWA5A | c.505C>T p.P169S | Missense Mutation (SNP) | VAF 168/251 reads (67%) | SIFT tolerated (0.14); PolyPhen benign (0.061); catalogued as COSV63707457; called by muse, mutect2, varscan2
- ZNF735 | c.250G>C p.A84P | Missense Mutation (SNP) | VAF 155/467 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.203); catalogued as rs1168199640; called by muse, mutect2, varscan2
- ZNF804B | c.424A>G p.I142V | Missense Mutation (SNP) | VAF 47/99 reads (47%) | SIFT tolerated (0.72); PolyPhen benign (0.014); catalogued as rs768716684; called by muse, mutect2, varscan2
- ZNF804B | c.3524C>A p.S1175* | Nonsense Mutation (SNP) | VAF 184/449 reads (41%) | catalogued as COSV60815283, COSV60859921; called by muse, mutect2, varscan2
- ZP2 | c.65C>G p.T22S | Missense Mutation (SNP) | VAF 33/140 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.009); catalogued as rs748349567; called by muse, mutect2, varscan2
- A2M | c.1646G>T p.G549V | Missense Mutation (SNP) | VAF 98/382 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, varscan2
- ABCB5 | c.2519T>C p.L840P (on ENST00000404938 / NM_001163941.2; = p.L395P on NM_178559.6) | Missense Mutation (SNP) | VAF 88/421 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.673); called by muse, mutect2, varscan2
- ADAMTS1 | c.2144G>T p.G715V | Missense Mutation (SNP) | VAF 110/293 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- ADAMTS5 | c.999C>A p.N333K | Missense Mutation (SNP) | VAF 192/479 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ADAMTSL1 | c.1361A>G p.Q454R | Missense Mutation (SNP) | VAF 66/178 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- ADGRA3 | c.3793G>T p.A1265S | Missense Mutation (SNP) | VAF 106/242 reads (44%) | SIFT tolerated (0.93); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- AHNAK | c.6343_6345del p.P2115del | In Frame Del (DEL) | VAF 176/330 reads (53%) | called by mutect2, pindel, varscan2
- ALB | c.842G>A p.R281K | Missense Mutation (SNP) | VAF 252/567 reads (44%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- AMER3 | c.2159A>T p.K720I | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- ANGPT1 | c.616A>T p.K206* | Nonsense Mutation (SNP) | VAF 208/422 reads (49%) | called by muse, mutect2, varscan2
- ANKRD30B | c.536C>A p.A179D | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- ANO5 | c.2496G>T p.K832N | Missense Mutation (SNP) | VAF 192/406 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- APEX1 | c.88G>T p.A30S | Missense Mutation (SNP) | VAF 66/214 reads (31%) | SIFT tolerated (0.75); PolyPhen benign (0.186); called by muse, mutect2, varscan2
- ARAP2 | c.2603A>T p.H868L | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- ARHGAP15 | c.474G>T p.Q158H | Missense Mutation (SNP) | VAF 151/334 reads (45%) | SIFT tolerated (0.62); PolyPhen benign (0.395); called by muse, mutect2, varscan2
- ARHGAP15 | c.474+1G>T p.X158_splice | Splice Site (SNP) | VAF 146/327 reads (45%) | called by muse, mutect2, varscan2
- ARMC4 | c.1229A>T p.Q410L | Missense Mutation (SNP) | VAF 34/211 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- ARRDC5 | c.218C>A p.S73Y (on ENST00000381781; = p.S59Y on NM_001080523.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 142/230 reads (62%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.837); called by muse, varscan2
- ARRDC5 | c.141C>A p.S47R (on ENST00000381781; = p.S33R on NM_001080523.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 217/374 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- ASB8 | c.449A>T p.N150I | Missense Mutation (SNP) | VAF 104/231 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ASTN1 | c.3434G>T p.C1145F | Missense Mutation (SNP) | VAF 25/226 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ASTN2 | c.3514G>T p.V1172L (on ENST00000313400 / NM_001365069.1; = p.V1121L on NM_014010.5) | Missense Mutation (SNP) | VAF 165/414 reads (40%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- ASXL3 | c.4134del p.S1379Vfs*13 | Frame Shift Del (DEL) | VAF 62/205 reads (30%) | called by pindel, varscan2
- ATF7IP | c.634G>T p.G212C | Missense Mutation (SNP) | VAF 85/224 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.614); called by muse, mutect2, varscan2
- ATP13A2 | c.2830C>G p.Q944E | Missense Mutation (SNP) | VAF 87/399 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.348); called by muse, mutect2, varscan2
- BARHL2 | c.152C>G p.P51R | Missense Mutation (SNP) | VAF 62/332 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.855); called by muse, mutect2, varscan2
- BCLAF3 | c.1232_1235del p.L411Qfs*4 | Frame Shift Del (DEL) | VAF 10/16 reads (63%) | called by mutect2, varscan2
- BTK | c.1639C>A p.L547M | Missense Mutation (SNP) | VAF 82/116 reads (71%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- C4orf54 | c.649C>A p.H217N | Missense Mutation (SNP) | VAF 30/404 reads (7%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0.003); called by muse, mutect2
- C5 | c.313G>T p.E105* | Nonsense Mutation (SNP) | VAF 42/138 reads (30%) | called by muse, varscan2
- CACNA1B | c.1076T>G p.F359C | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, varscan2
- CAMK2N2 | c.230C>A p.S77Y | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.202); called by muse, mutect2, varscan2
- CCAR1 | c.457G>T p.V153L | Missense Mutation (SNP) | VAF 100/250 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.279); called by muse, mutect2, varscan2
- CCDC39 | c.1751C>G p.S584C | Missense Mutation (SNP) | VAF 44/159 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); called by muse, varscan2
- CDH23 | c.2290-1G>T p.X764_splice | Splice Site (SNP) | VAF 79/206 reads (38%) | called by muse, mutect2, varscan2
- CDH23 | c.2290G>T p.V764L | Missense Mutation (SNP) | VAF 80/206 reads (39%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CDH23 | c.9046C>A p.R3016S | Missense Mutation (SNP) | VAF 78/190 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.364); called by muse, mutect2, varscan2
- CFAP300 | c.693C>G p.C231W | Missense Mutation (SNP) | VAF 75/100 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- CFAP54 | c.7978C>A p.L2660I | Missense Mutation (SNP) | VAF 24/102 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); called by muse, varscan2
- CHADL | c.2082_2087delinsA p.N694Kfs*25 | Frame Shift Del (DEL) | VAF 18/32 reads (56%) | called by pindel, varscan2*
- CHRM5 | c.1148T>A p.L383* | Nonsense Mutation (SNP) | VAF 140/355 reads (39%) | called by muse, mutect2, varscan2
- CMYA5 | c.3779T>C p.L1260P | Missense Mutation (SNP) | VAF 58/166 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, varscan2
- COL11A1 | c.5338A>T p.I1780F | Missense Mutation (SNP) | VAF 51/137 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0.434); called by muse, mutect2, varscan2
- COL23A1 | c.368C>A p.P123H | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- COL6A5 | c.1240C>T p.Q414* | Nonsense Mutation (SNP) | VAF 14/49 reads (29%) | called by muse, mutect2, varscan2
- COPA | c.1364A>C p.E455A | Missense Mutation (SNP) | VAF 44/290 reads (15%) | SIFT tolerated (0.43); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- CST11 | c.381G>T p.Q127H (on ENST00000377009 / NM_130794.2; = p.Q92H on NM_080830.3) | Missense Mutation (SNP) | VAF 61/152 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- DACH1 | c.1871A>T p.N624I (on ENST00000619232 / NM_001366712.1; = p.N370I on NM_004392.6) | Missense Mutation (SNP) | VAF 38/114 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.924); called by muse, varscan2
- DCAF8L2 | c.1061C>T p.A354V | Missense Mutation (SNP) | VAF 70/137 reads (51%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.657); called by muse, mutect2, varscan2
- DCAF8L2 | c.1544C>A p.T515K | Missense Mutation (SNP) | VAF 61/101 reads (60%) | SIFT tolerated (0.07); PolyPhen benign (0.376); called by muse, mutect2, varscan2
- DCLRE1B | c.691G>T p.A231S | Missense Mutation (SNP) | VAF 55/255 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.909); called by muse, mutect2, varscan2
- DHX29 | c.3170G>T p.G1057V | Missense Mutation (SNP) | VAF 195/514 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DIO2 | c.595C>A p.L199M | Missense Mutation (SNP) | VAF 101/306 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- DNAH8 | c.7328A>T p.D2443V | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.471); called by muse, mutect2, varscan2
- DPP6 | c.2207G>T p.G736V (on ENST00000377770 / NM_001364500.2; = p.G674V on NM_001936.5) | Missense Mutation (SNP) | VAF 71/272 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- DSG3 | c.1969C>A p.P657T | Missense Mutation (SNP) | VAF 143/547 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.78); called by muse, mutect2, varscan2
- DTX1 | c.187G>A p.G63R | Missense Mutation (SNP) | VAF 74/159 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EIF5B | c.1346A>G p.K449R | Missense Mutation (SNP) | VAF 147/459 reads (32%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- ELAPOR2 | c.2929G>T p.A977S (on ENST00000450689 / NM_001142749.3; = p.A810S on NM_152748.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 75/286 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.841); called by muse, mutect2, varscan2
- EPAS1 | c.755T>A p.M252K | Missense Mutation (SNP) | VAF 205/303 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EXPH5 | c.4980T>A p.S1660R | Missense Mutation (SNP) | VAF 64/113 reads (57%) | SIFT deleterious (0.03); PolyPhen benign (0.132); called by muse, mutect2, varscan2
- FAM78B | c.300A>T p.R100S | Missense Mutation (SNP) | VAF 41/57 reads (72%) | SIFT tolerated (0.12); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- FMNL2 | c.291A>T p.R97S | Missense Mutation (SNP) | VAF 114/234 reads (49%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.962); called by muse, varscan2
- FSIP2 | c.10067T>A p.M3356K | Missense Mutation (SNP) | VAF 122/176 reads (69%) | SIFT deleterious (0); PolyPhen benign (0); called by muse, varscan2
- GABRB3 | c.136G>T p.V46L | Missense Mutation (SNP) | VAF 99/286 reads (35%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); called by muse, mutect2, varscan2
- GBP5 | c.593A>C p.E198A | Missense Mutation (SNP) | VAF 36/180 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.153); called by muse, mutect2, varscan2
- GDPD4 | c.1342G>A p.D448N | Missense Mutation (SNP) | VAF 171/244 reads (70%) | SIFT tolerated (0.38); PolyPhen benign (0.097); called by muse, varscan2
- GJB5 | c.656C>G p.A219G | Missense Mutation (SNP) | VAF 63/296 reads (21%) | SIFT tolerated (0.34); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GLIPR1L1 | c.338C>T p.A113V | Missense Mutation (SNP) | VAF 90/260 reads (35%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.893); called by muse, varscan2
- GOLGA4 | c.4875G>T p.L1625F | Missense Mutation (SNP) | VAF 48/216 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, varscan2
- GREB1 | c.5386A>T p.I1796F | Missense Mutation (SNP) | VAF 80/121 reads (66%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- GRIK1 | c.211C>A p.L71M | Missense Mutation (SNP) | VAF 42/269 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HAS1 | c.416C>A p.A139D | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT tolerated (0.58); PolyPhen benign (0); called by muse, mutect2, varscan2
- HGFAC | c.1854G>T p.W618C | Missense Mutation (SNP) | VAF 31/64 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HMCN2 | c.5031C>A p.D1677E | Missense Mutation (SNP) | VAF 46/168 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- HOXB9 | c.133C>A p.L45M | Missense Mutation (SNP) | VAF 94/233 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- HTR1E | c.536A>G p.H179R | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- IGKV1D-13 | c.223A>T p.S75C | Missense Mutation (SNP) | VAF 103/757 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); called by muse, mutect2, varscan2
- IGKV1D-16 | c.66T>A p.C22* | Nonsense Mutation (SNP) | VAF 247/590 reads (42%) | called by muse, mutect2, varscan2
- ITPR1 | c.280-2A>T p.X94_splice | Splice Site (SNP) | VAF 37/125 reads (30%) | called by muse, mutect2, varscan2
- JHY | c.709G>T p.E237* | Nonsense Mutation (SNP) | VAF 128/191 reads (67%) | called by muse, mutect2, varscan2
- KCNH8 | c.2815A>G p.T939A | Missense Mutation (SNP) | VAF 73/283 reads (26%) | SIFT tolerated, low confidence (0.77); PolyPhen benign (0); called by muse, mutect2, varscan2
- KIAA1109 | c.5158C>T p.L1720F | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- KIF18A | c.857T>C p.L286S | Missense Mutation (SNP) | VAF 101/518 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KIF19 | c.2408C>T p.P803L | Missense Mutation (SNP) | VAF 57/158 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- KIF26A | c.4816G>T p.G1606C | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.593); called by muse, mutect2, varscan2
- KIF5A | c.2620G>T p.A874S | Missense Mutation (SNP) | VAF 198/470 reads (42%) | SIFT tolerated (0.3); PolyPhen benign (0.222); called by muse, mutect2, varscan2
- KLK8 | c.221G>T p.C74F | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- KRTAP10-2 | c.552_553del p.S185Rfs*29 | Frame Shift Del (DEL) | VAF 72/400 reads (18%) | called by pindel, varscan2
- KRTAP5-6 | c.317dup p.S107Vfs*27 | Frame Shift Ins (INS) | VAF 147/369 reads (40%) | called by mutect2, pindel, varscan2
- KRTAP7-1 | c.178A>C p.N60H | Missense Mutation (SNP) | VAF 32/190 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.974); called by muse, mutect2
- LCE5A | c.337A>G p.S113G | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- LMNA | c.243_244del p.Y81* | Nonsense Mutation (DEL) | VAF 21/127 reads (17%) | called by mutect2, pindel*, varscan2
- LRP1B | c.7340C>T p.P2447L | Missense Mutation (SNP) | VAF 72/278 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, varscan2
- LRRC7 | c.186C>G p.I62M (on ENST00000651989 / NM_001370785.2; = p.I29M on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 186/428 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- LTBP2 | c.2919A>T p.E973D | Missense Mutation (SNP) | VAF 173/448 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MACF1 | c.8261G>T p.R2754I | Missense Mutation (SNP) | VAF 41/158 reads (26%) | called by muse, mutect2, varscan2
- MACF1 | c.12308G>T p.R4103L (on ENST00000372915; = p.R2036L on NM_012090.5) | Missense Mutation (SNP) | VAF 68/363 reads (19%) | called by muse, mutect2, varscan2
- MGAM | c.4374C>A p.S1458R | Missense Mutation (SNP) | VAF 258/617 reads (42%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.99); called by muse, varscan2
- MRC1 | c.358G>T p.G120C | Missense Mutation (SNP) | VAF 252/798 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MS4A5 | c.422T>A p.L141Q | Missense Mutation (SNP) | VAF 132/196 reads (67%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.979); called by muse, varscan2
- MYO18B | c.5553G>T p.L1851F | Missense Mutation (SNP) | VAF 91/148 reads (61%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.629); called by muse, mutect2, varscan2
- MYO19 | c.2108C>A p.T703K (on ENST00000614623 / NM_001163735.1; = p.T503K on NM_025109.5) | Missense Mutation (SNP) | VAF 45/105 reads (43%) | SIFT tolerated (0.24); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- MYO6 | c.2107G>T p.G703C | Missense Mutation (SNP) | VAF 130/400 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MYPN | c.1975G>A p.D659N | Missense Mutation (SNP) | VAF 114/330 reads (35%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MYPN | c.2025C>G p.H675Q | Missense Mutation (SNP) | VAF 108/287 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- NDUFA12 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 69/216 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.465); called by muse, mutect2, varscan2
- NES | c.4571A>T p.E1524V | Missense Mutation (SNP) | VAF 46/344 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.175); called by muse, mutect2, varscan2
- NLRP12 | c.2620G>C p.D874H | Missense Mutation (SNP) | VAF 246/642 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- NPAS3 | c.559-1G>T p.X187_splice (on ENST00000356141 / NM_001164749.2; = p.X155_splice on NM_022123.3) | Splice Site (SNP) | VAF 91/342 reads (27%) | called by muse, mutect2, varscan2
- NPY5R | c.215A>T p.Q72L | Missense Mutation (SNP) | VAF 69/161 reads (43%) | SIFT tolerated (0.24); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- OCLNP1 | n.147+1G>C | Splice Site (SNP) | VAF 54/336 reads (16%) | called by muse, mutect2, varscan2
- OR10J1 | c.72G>T p.Q24H | Missense Mutation (SNP) | VAF 82/602 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.013); called by muse, varscan2
- OR10V1 | c.844A>G p.I282V | Missense Mutation (SNP) | VAF 149/235 reads (63%) | SIFT tolerated (1); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- OR11H1 | c.549_550del p.C183* | Frame Shift Del (DEL) | VAF 164/662 reads (25%) | called by pindel, varscan2
- OR4C46 | c.897G>T p.L299F | Missense Mutation (SNP) | VAF 12/20 reads (60%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.111); called by muse, mutect2
- OR51C1P | c.730C>A p.H244N | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- OR6C65 | c.109G>T p.V37L | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- PDZD2 | c.3328A>G p.K1110E | Missense Mutation (SNP) | VAF 26/145 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); called by muse, mutect2, varscan2
- PHF2 | c.1210G>T p.G404C | Missense Mutation (SNP) | VAF 61/369 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- PHF2 | c.2306A>G p.Q769R | Missense Mutation (SNP) | VAF 97/462 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- PIEZO2 | c.3173G>A p.R1058K | Missense Mutation (SNP) | VAF 119/314 reads (38%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- PIK3R4 | c.2847G>T p.Q949H | Missense Mutation (SNP) | VAF 47/194 reads (24%) | SIFT tolerated (0.59); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- PLXDC2 | c.303G>T p.Q101H | Missense Mutation (SNP) | VAF 78/244 reads (32%) | SIFT tolerated (0.65); PolyPhen benign (0); called by muse, mutect2, varscan2
- PMCH | c.437G>C p.R146T | Missense Mutation (SNP) | VAF 64/163 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- PPP1R10 | c.85G>A p.D29N | Missense Mutation (SNP) | VAF 57/310 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.156); called by muse, mutect2, varscan2
- PPP4R3A | c.1972A>G p.S658G (on ENST00000554943 / NM_001366432.1; = p.S645G on NM_001284280.1) | Missense Mutation (SNP) | VAF 92/242 reads (38%) | SIFT tolerated (0.24); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- PRDM8 | c.1960A>T p.M654L | Missense Mutation (SNP) | VAF 193/425 reads (45%) | SIFT tolerated (0.17); PolyPhen benign (0); called by muse, mutect2, varscan2
- PREX2 | c.2911G>T p.D971Y | Missense Mutation (SNP) | VAF 60/242 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.305); called by muse, varscan2
- PRG4 | c.794del p.P265Hfs*12 | Frame Shift Del (DEL) | VAF 104/938 reads (11%) | called by mutect2, pindel, varscan2
- PRKDC | c.6790G>T p.D2264Y | Missense Mutation (SNP) | VAF 102/256 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- PRSS55 | c.115C>A p.H39N | Missense Mutation (SNP) | VAF 37/88 reads (42%) | SIFT tolerated (0.31); PolyPhen benign (0); called by muse, mutect2, varscan2
- PRUNE2 | c.1600G>T p.A534S | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.206); called by muse, mutect2, varscan2
- RAB21 | c.501A>T p.K167N | Missense Mutation (SNP) | VAF 61/179 reads (34%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.667); called by muse, mutect2, varscan2
- RABGAP1L | c.463A>G p.M155V | Missense Mutation (SNP) | VAF 110/435 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.196); called by muse, mutect2, varscan2
- RAF1 | c.772A>T p.T258S | Missense Mutation (SNP) | VAF 89/314 reads (28%) | SIFT tolerated (0.54); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- RASAL2 | c.1039G>T p.D347Y | Missense Mutation (SNP) | VAF 44/151 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RGS9 | c.1794G>T p.R598S | Missense Mutation (SNP) | VAF 82/224 reads (37%) | SIFT tolerated, low confidence (0.78); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ROM1 | c.41G>T p.R14L | Missense Mutation (SNP) | VAF 89/111 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- RSPH3 | c.692C>G p.A231G (on ENST00000252655; = p.A89G on NM_031924.8) | Missense Mutation (SNP) | VAF 54/227 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- RUBCNL | c.1409G>T p.C470F | Missense Mutation (SNP) | VAF 33/99 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.166); called by muse, mutect2, varscan2
- RXRG | c.472G>T p.G158C | Missense Mutation (SNP) | VAF 24/146 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RYR2 | c.12239A>T p.Y4080F | Missense Mutation (SNP) | VAF 41/239 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- SATL1 | c.424C>A p.P142T (on ENST00000395409; = p.P329T on NM_001012980.2) | Missense Mutation (SNP) | VAF 156/226 reads (69%) | SIFT deleterious (0.02); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- SAXO1 | c.1024G>T p.D342Y | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- SBK2 | c.254-1G>T p.X85_splice | Splice Site (SNP) | VAF 27/56 reads (48%) | called by muse, mutect2, varscan2
- SEC16A | c.6872del p.S2291Cfs*6 | Frame Shift Del (DEL) | VAF 57/180 reads (32%) | called by mutect2, pindel, varscan2
- SELP | c.1043C>A p.S348Y | Missense Mutation (SNP) | VAF 270/484 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SEPTIN5 | c.1018G>T p.E340* | Nonsense Mutation (SNP) | VAF 75/127 reads (59%) | called by muse, mutect2, varscan2
- SETD3 | c.489_490del p.C163* | Nonsense Mutation (DEL) | VAF 76/290 reads (26%) | called by pindel, varscan2
- SHOX | c.532C>A p.Q178K | Missense Mutation (SNP) | VAF 85/378 reads (22%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- SLC12A3 | c.524T>C p.I175T | Missense Mutation (SNP) | VAF 203/459 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- SLC13A3 | c.1216A>T p.K406* | Nonsense Mutation (SNP) | VAF 173/329 reads (53%) | called by muse, mutect2, varscan2
- SORCS3 | c.23G>T p.R8L | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SPAG17 | c.4919C>G p.P1640R | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- SPTBN4 | c.7238C>T p.P2413L | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SS18L1 | c.617A>G p.Q206R | Missense Mutation (SNP) | VAF 296/511 reads (58%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.321); called by muse, mutect2, varscan2
- SSX3 | c.107A>T p.E36V | Missense Mutation (SNP) | VAF 58/105 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- ST3GAL4 | c.-60-4C>T | Splice Region (SNP) | VAF 113/163 reads (69%) | called by muse, mutect2, varscan2
- STAMBPL1 | c.274C>T p.H92Y | Missense Mutation (SNP) | VAF 27/85 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- STYXL1 | c.755del p.R252Pfs*7 | Frame Shift Del (DEL) | VAF 74/336 reads (22%) | called by mutect2, pindel*
- SYNE1 | c.13790A>G p.E4597G (on ENST00000367255 / NM_182961.4; = p.E4526G on NM_033071.3) | Missense Mutation (SNP) | VAF 116/336 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.024); called by muse, varscan2
- TAOK1 | c.372A>T p.Q124H | Missense Mutation (SNP) | VAF 53/149 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- TBC1D32 | c.287A>T p.Q96L | Missense Mutation (SNP) | VAF 35/136 reads (26%) | SIFT tolerated (0.53); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- TCHH | c.4154G>T p.R1385L | Missense Mutation (SNP) | VAF 208/349 reads (60%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- TENM3 | c.1268A>T p.Q423L | Missense Mutation (SNP) | VAF 68/132 reads (52%) | SIFT tolerated (0.08); PolyPhen benign (0.346); called by muse, mutect2, varscan2
- TMEM131 | c.4916G>T p.G1639V | Missense Mutation (SNP) | VAF 72/234 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.248); called by muse, mutect2, varscan2
- TMPRSS9 | c.1433C>A p.P478H (on ENST00000648592; = p.P444H on NM_182973.2) | Missense Mutation (SNP) | VAF 48/67 reads (72%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.847); called by muse, mutect2, varscan2
- TRAV22 | c.10A>T p.I4L | Missense Mutation (SNP) | VAF 138/346 reads (40%) | SIFT tolerated (0.8); PolyPhen benign (0); called by muse, varscan2
- TRBV28 | c.201C>A p.F67L | Missense Mutation (SNP) | VAF 94/278 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- TRBV7-1 | c.301A>T p.T101S | Missense Mutation (SNP) | VAF 48/166 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.177); called by muse, mutect2, varscan2
- TRIM69 | c.904T>A p.Y302N (on ENST00000329464 / NM_182985.5; = p.Y143N on NM_080745.5) | Missense Mutation (SNP) | VAF 88/228 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.328); called by muse, mutect2, varscan2
- TRIO | c.8588C>G p.T2863S | Missense Mutation (SNP) | VAF 68/358 reads (19%) | SIFT tolerated (0.62); PolyPhen benign (0.25); called by muse, mutect2, varscan2
- TRPV2 | c.634C>G p.P212A | Missense Mutation (SNP) | VAF 14/24 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); called by muse, varscan2
- TSBP1 | c.1412G>T p.S471I (on ENST00000617061; = p.S476I on NM_006781.5) | Missense Mutation (SNP) | VAF 269/572 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- TSHZ2 | c.170G>T p.G57V | Missense Mutation (SNP) | VAF 315/580 reads (54%) | SIFT tolerated (0.08); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- TSLP | c.320C>A p.A107D | Missense Mutation (SNP) | VAF 61/119 reads (51%) | SIFT tolerated (0.11); PolyPhen benign (0.257); called by muse, mutect2, varscan2
- TUBG1 | c.245A>C p.Y82S | Missense Mutation (SNP) | VAF 106/488 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.69); called by muse, mutect2
- UBE3C | c.2807G>T p.C936F | Missense Mutation (SNP) | VAF 56/161 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); called by muse, mutect2, varscan2
- UBR4 | c.5962G>T p.D1988Y | Missense Mutation (SNP) | VAF 100/230 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, varscan2
- USH2A | c.13195C>G p.L4399V | Missense Mutation (SNP) | VAF 259/447 reads (58%) | SIFT tolerated (0.24); PolyPhen benign (0.131); called by muse, mutect2, varscan2
- USH2A | c.8253C>A p.N2751K | Missense Mutation (SNP) | VAF 38/318 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, varscan2
- USP15 | c.57_59dup p.L20dup | In Frame Ins (INS) | VAF 28/154 reads (18%) | called by pindel, varscan2
- USP15 | c.60_61insTG p.K21* | Frame Shift Ins (INS) | VAF 40/162 reads (25%) | called by muse*, mutect2, varscan2*
- USP35 | c.461G>A p.C154Y | Missense Mutation (SNP) | VAF 90/110 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- VSTM4 | c.778C>G p.P260A | Missense Mutation (SNP) | VAF 120/397 reads (30%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- WDR1 | c.17-1G>T p.X6_splice | Splice Site (SNP) | VAF 64/143 reads (45%) | called by muse, mutect2, varscan2
- XPO6 | c.2853G>T p.R951S | Missense Mutation (SNP) | VAF 68/360 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- ZBTB5 | c.1890G>C p.K630N | Missense Mutation (SNP) | VAF 258/672 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.361); called by muse, mutect2
- ZBTB5 | c.1888A>C p.K630Q | Missense Mutation (SNP) | VAF 254/668 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.487); called by muse, mutect2
- ZDBF2 | c.5230G>A p.D1744N | Missense Mutation (SNP) | VAF 153/216 reads (71%) | SIFT tolerated (0.17); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- ZNF208 | c.3775G>T p.G1259C | Missense Mutation (SNP) | VAF 81/209 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF334 | c.1722T>G p.C574W | Missense Mutation (SNP) | VAF 54/443 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF468 | c.845A>T p.H282L | Missense Mutation (SNP) | VAF 75/230 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.123); called by muse, mutect2, varscan2
- ZNF490 | c.614G>T p.R205L | Missense Mutation (SNP) | VAF 90/166 reads (54%) | SIFT tolerated (0.22); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- ZNF530 | c.1730G>A p.C577Y | Missense Mutation (SNP) | VAF 47/117 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF662 | c.965A>T p.H322L | Missense Mutation (SNP) | VAF 52/191 reads (27%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZSWIM3 | c.1415C>G p.T472S | Missense Mutation (SNP) | VAF 345/566 reads (61%) | SIFT tolerated (0.47); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- ABCC1 | c.4242C>T p.A1414= | Silent (SNP) | VAF 29/150 reads (19%) | called by muse, mutect2, varscan2
- ACSM4 | c.756C>A p.L252= | Silent (SNP) | VAF 27/79 reads (34%) | called by muse, mutect2, varscan2
- ADGRB1 | c.4626G>A p.T1542= | Silent (SNP) | VAF 76/229 reads (33%) | catalogued as rs1006191676, COSV60102129; called by muse, varscan2
- AHNAK2 | c.2301G>A p.K767= | Silent (SNP) | VAF 56/217 reads (26%) | catalogued as rs747383496, COSV60930557; called by muse, mutect2, varscan2
- AKAP13 | c.798A>G p.P266= | Silent (SNP) | VAF 102/418 reads (24%) | catalogued as rs1415799676; called by muse, varscan2
- ALKAL1 | c.147C>A p.P49= | Silent (SNP) | VAF 9/33 reads (27%) | called by muse, mutect2, varscan2
- ASNS | c.1191C>G p.L397= | Silent (SNP) | VAF 260/652 reads (40%) | called by muse, mutect2, varscan2
- CHAMP1 | c.1857C>T p.L619= | Silent (SNP) | VAF 34/83 reads (41%) | called by muse, varscan2
- CYLD | c.666A>T p.T222= | Silent (SNP) | VAF 169/417 reads (41%) | called by muse, mutect2, varscan2
- DDX60 | c.942C>T p.L314= | Silent (SNP) | VAF 41/79 reads (52%) | catalogued as rs150120023; called by muse, mutect2, varscan2
- DZIP1 | c.87C>T p.P29= | Silent (SNP) | VAF 11/41 reads (27%) | called by muse, mutect2, varscan2
- DZIP3 | c.2091A>G p.S697= | Silent (SNP) | VAF 48/186 reads (26%) | catalogued as rs1357283445; called by muse, mutect2, varscan2
- EPHA10 | c.633C>T p.C211= | Silent (SNP) | VAF 44/87 reads (51%) | called by muse, mutect2, varscan2
- ERCC6 | c.1749G>A p.K583= | Silent (SNP) | VAF 247/667 reads (37%) | catalogued as rs750222428; called by muse, mutect2, varscan2
- F5 | c.6006C>A p.I2002= | Silent (SNP) | VAF 273/420 reads (65%) | called by muse, mutect2, varscan2
- FAM78B | c.510G>T p.T170= | Silent (SNP) | VAF 16/117 reads (14%) | called by muse, mutect2, varscan2
- FIG4 | c.945A>G p.A315= | Silent (SNP) | VAF 42/141 reads (30%) | called by muse, mutect2, varscan2
- FSIP2 | c.20118G>C p.T6706= | Silent (SNP) | VAF 63/431 reads (15%) | catalogued as rs779866454, COSV58090474, COSV58100545; called by muse, mutect2, varscan2
- GPR6 | c.534G>T p.S178= | Silent (SNP) | VAF 67/217 reads (31%) | catalogued as COSV51573910; called by muse, mutect2, varscan2
- GRID2 | c.642C>A p.T214= | Silent (SNP) | VAF 54/319 reads (17%) | called by muse, mutect2, varscan2
- HAS1 | c.417C>A p.A139= | Silent (SNP) | VAF 19/72 reads (26%) | called by muse, mutect2, varscan2
- HNF4G | c.1149G>T p.G383= (on ENST00000354370 / NM_001330561.2; = p.G430= on NM_004133.5) | Silent (SNP) | VAF 92/390 reads (24%) | called by muse, mutect2, varscan2
- HSFX1 | c.294C>A p.P98= | Silent (SNP) | VAF 5/9 reads (56%) | called by mutect2, varscan2
- KCNB2 | c.702A>G p.A234= | Silent (SNP) | VAF 276/615 reads (45%) | called by muse, mutect2, varscan2
- KRT34 | c.198C>A p.P66= | Silent (SNP) | VAF 68/195 reads (35%) | catalogued as rs148417834; called by muse, mutect2, varscan2
- LIMA1 | c.621T>G p.T207= | Silent (SNP) | VAF 14/41 reads (34%) | called by muse, mutect2, varscan2
- LRFN5 | c.651G>A p.Q217= | Silent (SNP) | VAF 47/198 reads (24%) | called by muse, mutect2, varscan2
- LRRC2 | c.507G>T p.L169= | Silent (SNP) | VAF 20/80 reads (25%) | called by muse, mutect2, varscan2
- LY9 | c.1485A>T p.P495= | Silent (SNP) | VAF 48/487 reads (10%) | called by muse, mutect2, varscan2
- MAGEC1 | c.2145T>A p.P715= | Silent (SNP) | VAF 19/42 reads (45%) | called by muse, mutect2, varscan2
- MYO18B | c.4305A>G p.L1435= | Silent (SNP) | VAF 73/117 reads (62%) | called by muse, mutect2, varscan2
- NOTCH1 | c.1047C>T p.T349= | Silent (SNP) | VAF 16/186 reads (9%) | catalogued as rs755872359; called by muse, mutect2, varscan2
- NPR3 | c.309C>T p.Y103= | Silent (SNP) | VAF 76/266 reads (29%) | catalogued as rs1561074830, COSV54085671; called by muse, mutect2, varscan2
- NWD1 | c.3252A>G p.P1084= | Silent (SNP) | VAF 60/114 reads (53%) | called by muse, mutect2, varscan2
- OCSTAMP | c.459C>A p.T153= | Silent (SNP) | VAF 81/296 reads (27%) | catalogued as COSV99645460; called by muse, mutect2, varscan2
- OR14A2 | c.438C>A p.S146= | Silent (SNP) | VAF 58/193 reads (30%) | called by muse, mutect2, varscan2
- OR4D2 | c.588G>A p.E196= | Silent (SNP) | VAF 332/872 reads (38%) | catalogued as COSV73459746; called by muse, mutect2, varscan2
- OR51E2 | c.669G>T p.T223= | Silent (SNP) | VAF 163/290 reads (56%) | called by muse, varscan2
- OR5AC2 | c.468G>A p.L156= | Silent (SNP) | VAF 38/130 reads (29%) | called by muse, mutect2, varscan2
- OR9K2 | c.324C>A p.I108= (on ENST00000305377; = p.I86= on NM_001005243.1) | Silent (SNP) | VAF 72/212 reads (34%) | catalogued as COSV59532247; called by muse, mutect2
- PHF8 | c.2526A>G p.G842= (on ENST00000357988 / NM_001184896.1; = p.G806= on NM_015107.3) | Silent (SNP) | VAF 180/222 reads (81%) | called by muse, mutect2, varscan2
- PIP4P2 | c.102C>G p.P34= | Silent (SNP) | VAF 139/546 reads (25%) | called by muse, mutect2, varscan2
- PLRG1 | c.222G>A p.T74= | Silent (SNP) | VAF 40/301 reads (13%) | catalogued as rs780782912, COSV57423205; called by muse, mutect2, varscan2
- POM121L2 | c.975G>A p.P325= | Silent (SNP) | VAF 70/224 reads (31%) | catalogued as rs370831304; called by muse, mutect2, varscan2
- PREX2 | c.2730G>A p.L910= | Silent (SNP) | VAF 58/236 reads (25%) | called by muse, varscan2
- PROM2 | c.648C>T p.S216= | Silent (SNP) | VAF 190/478 reads (40%) | catalogued as COSV58299137; called by muse, mutect2, varscan2
- PRUNE2 | c.2688A>G p.P896= | Silent (SNP) | VAF 66/140 reads (47%) | called by muse, mutect2, varscan2
- PTPRD | c.447C>G p.A149= | Silent (SNP) | VAF 150/479 reads (31%) | called by muse, mutect2, varscan2
- RAP1GAP | c.744G>A p.G248= | Silent (SNP) | VAF 64/135 reads (47%) | called by muse, mutect2, varscan2
- RASGRP4 | c.352C>A p.R118= | Silent (SNP) | VAF 96/322 reads (30%) | called by muse, mutect2, varscan2
- RYR1 | c.10821C>T p.D3607= | Silent (SNP) | VAF 56/131 reads (43%) | catalogued as COSV62094547; called by muse, mutect2, varscan2
- SCN5A | c.282C>T p.I94= | Silent (SNP) | VAF 22/81 reads (27%) | catalogued as COSV100028402, COSV60067676; called by muse, mutect2, varscan2
- SP100 | c.114C>T p.F38= | Silent (SNP) | VAF 146/202 reads (72%) | called by muse, mutect2, varscan2
- ST6GAL2 | c.1158G>T p.P386= | Silent (SNP) | VAF 51/122 reads (42%) | called by muse, mutect2, varscan2
- STMN3 | c.99C>T p.T33= | Silent (SNP) | VAF 24/446 reads (5%) | catalogued as rs750619499, COSV100899877; called by muse, mutect2
- STYXL2 | c.2394G>A p.V798= | Silent (SNP) | VAF 132/242 reads (55%) | called by muse, mutect2, varscan2
- SVEP1 | c.9732T>A p.P3244= | Silent (SNP) | VAF 99/254 reads (39%) | called by muse, mutect2, varscan2
- TAF1 | c.3528C>T p.R1176= (on ENST00000373790 / NM_138923.4; = p.R1197= on NM_004606.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 89/134 reads (66%) | called by muse, mutect2, varscan2
- TAF1C | c.1932A>G p.L644= | Silent (SNP) | VAF 114/369 reads (31%) | called by muse, mutect2, varscan2
- TENM4 | c.534G>T p.T178= | Silent (SNP) | VAF 98/124 reads (79%) | called by muse, mutect2, varscan2
- THSD7A | c.3942G>T p.V1314= | Silent (SNP) | VAF 36/199 reads (18%) | called by muse, mutect2, varscan2
- TMEM121B | c.120G>A p.R40= | Silent (SNP) | VAF 8/120 reads (7%) | called by muse, mutect2
- TMEM144 | c.915A>T p.I305= | Silent (SNP) | VAF 45/139 reads (32%) | called by muse, mutect2, varscan2
- TPTE | c.456G>A p.Q152= (on ENST00000618007 / NM_199261.4; = p.Q134= on NM_199259.4) | Silent (SNP) | VAF 42/215 reads (20%) | catalogued as rs758378612; called by muse, mutect2, varscan2
- TSTD2 | c.1347A>T p.G449= | Silent (SNP) | VAF 35/83 reads (42%) | called by muse, mutect2, varscan2
- USP46 | c.234G>T p.T78= | Silent (SNP) | VAF 65/297 reads (22%) | called by muse, mutect2, varscan2
- VWDE | c.4221A>T p.P1407= | Silent (SNP) | VAF 115/256 reads (45%) | called by muse, mutect2, varscan2
- XKR5 | c.630G>T p.V210= | Silent (SNP) | VAF 82/210 reads (39%) | called by muse, mutect2, varscan2
- XRN1 | c.2115T>C p.N705= | Silent (SNP) | VAF 44/129 reads (34%) | called by muse, varscan2
- ZNF224 | c.9G>T p.T3= | Silent (SNP) | VAF 35/111 reads (32%) | called by muse, mutect2, varscan2
- AC000120.2 | c.-372del | 5'UTR (DEL) | VAF 20/58 reads (34%) | called by mutect2, pindel
- AC073648.1 | n.716G>T | RNA (SNP) | VAF 10/69 reads (14%) | called by muse, mutect2
- AC136759.1 | n.846C>A | RNA (SNP) | VAF 22/108 reads (20%) | called by muse, mutect2, varscan2
- ACADVL | c.1077+9C>A | Intron (SNP) | VAF 119/403 reads (30%) | called by muse, mutect2, varscan2
- AFF1 | c.1038+2157G>C | Intron (SNP) | VAF 94/209 reads (45%) | catalogued as COSV100321215; called by muse, mutect2, varscan2
- AL450442.1 | n.752C>G | RNA (SNP) | VAF 67/226 reads (30%) | called by muse, mutect2, varscan2
- AREL1 | c.-333-6444G>T | Intron (SNP) | VAF 21/50 reads (42%) | called by muse, mutect2, varscan2
- ATP6V0D1 | c.302+1216C>T | Intron (SNP) | VAF 47/214 reads (22%) | called by muse, mutect2, varscan2
- AVPR2 | c.-62C>T | 5'UTR (SNP) | VAF 70/217 reads (32%) | called by muse, mutect2, varscan2
- CDR2 | c.-7A>T | 5'UTR (SNP) | VAF 29/61 reads (48%) | called by muse, mutect2, varscan2
- CES3 | c.426+24C>T | Intron (SNP) | VAF 39/96 reads (41%) | called by muse, mutect2, varscan2
- CLPTM1 | c.*110G>A | 3'UTR (SNP) | VAF 23/54 reads (43%) | catalogued as rs1334977711; called by muse, mutect2, varscan2
- CNOT11 | chr2:101273314 G>C | 3'Flank (SNP) | VAF 106/298 reads (36%) | called by muse, varscan2
- CNTNAP3 | c.*20C>T | 3'UTR (SNP) | VAF 87/929 reads (9%) | called by muse, mutect2
- COLCA2 | chr11:111296245 A>T | 5'Flank (SNP) | VAF 174/238 reads (73%) | called by muse, mutect2, varscan2
- DAO | chr12:108879609 C>G | 5'Flank (SNP) | VAF 23/49 reads (47%) | called by muse, mutect2, varscan2
- DCHS2 | n.314A>T | RNA (SNP) | VAF 86/375 reads (23%) | called by muse, mutect2, varscan2
- ENDOV | c.715-805G>T | Intron (SNP) | VAF 44/98 reads (45%) | called by muse, mutect2, varscan2
- ERBB2 | c.-51C>G | 5'UTR (SNP) | VAF 6/29 reads (21%) | called by mutect2, varscan2
- ERCC6 | c.1397+7038G>C | Intron (SNP) | VAF 35/142 reads (25%) | called by muse, mutect2, varscan2
- GABRA2 | c.1059+5645G>A | Intron (SNP) | VAF 23/111 reads (21%) | called by muse, varscan2
- GUSBP4 | n.96G>T | RNA (SNP) | VAF 22/497 reads (4%) | called by muse, mutect2
- HBE1 | c.-267+102196G>T | Intron (SNP) | VAF 141/277 reads (51%) | called by muse, mutect2, varscan2
- JAKMIP3 | c.*353G>C | 3'UTR (SNP) | VAF 88/259 reads (34%) | catalogued as rs777326383; called by muse, mutect2, varscan2
- KIZ | c.-2G>T | 5'UTR (SNP) | VAF 54/180 reads (30%) | called by muse, mutect2, varscan2
- LINC00917 | n.1564+1581C>A | Intron (SNP) | VAF 74/198 reads (37%) | called by muse, mutect2, varscan2
- MEX3B | c.256+167G>T | Intron (SNP) | VAF 19/40 reads (48%) | called by muse, mutect2, varscan2
- MOK | chr14:102226363 G>A | 3'Flank (SNP) | VAF 160/376 reads (43%) | called by muse, mutect2, varscan2
- NAPSA | c.-7C>T | 5'UTR (SNP) | VAF 73/181 reads (40%) | called by muse, mutect2, varscan2
- NLGN4Y | c.473-3623A>G | Intron (SNP) | VAF 39/66 reads (59%) | called by muse, varscan2
- RCOR2 | c.1258-32G>A | Intron (SNP) | VAF 211/281 reads (75%) | called by muse, mutect2, varscan2
- RNU6-1178P | chr17:20895828 C>G | 5'Flank (SNP) | VAF 14/119 reads (12%) | catalogued as COSV60001944; called by muse, mutect2, varscan2
- RPGR | c.2520+25G>T | Intron (SNP) | VAF 166/277 reads (60%) | called by muse, mutect2, varscan2
- SHOX | c.-46G>T | 5'UTR (SNP) | VAF 4/17 reads (24%) | catalogued as COSV100479307; called by muse, mutect2, varscan2
- SLC28A3 | c.-13C>T | 5'UTR (SNP) | VAF 34/173 reads (20%) | called by muse, mutect2, varscan2
- SLC4A1 | c.-55G>T | 5'UTR (SNP) | VAF 95/225 reads (42%) | catalogued as COSV99293320; called by muse, mutect2, varscan2
- SMPD4BP | n.2398C>T | RNA (SNP) | VAF 19/88 reads (22%) | called by muse, mutect2, varscan2
- SNORD114-31 | chr14:100989214 C>A | 5'Flank (SNP) | VAF 62/148 reads (42%) | catalogued as rs750801332; called by muse, varscan2
- SPAG9 | c.783+33del | Intron (DEL) | VAF 51/162 reads (31%) | catalogued as rs34651776; called by mutect2, pindel, varscan2
- SPATA18 | c.1479+66T>C | Intron (SNP) | VAF 43/213 reads (20%) | called by muse, mutect2, varscan2
- SSUH2 | c.-3-549G>T | Intron (SNP) | VAF 73/323 reads (23%) | called by muse, mutect2, varscan2
- STX4 | chr16:31033426 A>G | 5'Flank (SNP) | VAF 62/326 reads (19%) | called by muse, mutect2, varscan2
- TMX4 | c.176+442A>T | Intron (SNP) | VAF 95/202 reads (47%) | called by muse, mutect2, varscan2
- VLDLR | c.2587-34A>G | Intron (SNP) | VAF 120/331 reads (36%) | called by muse, mutect2, varscan2
- WT1 | chr11:32438175 G>A | 5'Flank (SNP) | VAF 35/158 reads (22%) | called by muse, mutect2, varscan2
- ZNF667 | c.254-6825G>T | Intron (SNP) | VAF 45/161 reads (28%) | called by muse, mutect2, varscan2
- ZNF667 | c.254-6826T>C | Intron (SNP) | VAF 45/161 reads (28%) | called by muse, mutect2, varscan2
